Somatic mutation profile of tumor specimen TCGA-06-2567-01A (aliquot TCGA-06-2567-01A-01D-1494-08) from TCGA case TCGA-06-2567, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 65.0 years (23,759 days).
Specimen TCGA-06-2567-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2ebf499-6ac9-42a3-b2ed-a9fd337b71bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-2567-10A (Blood Derived Normal), aliquot TCGA-06-2567-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a055c39-d774-46eb-8377-8ebc4d53632c

The open-access MAF lists 64 somatic variants for this specimen: 44 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 17, Nonsense Mutation 5, Frame Shift Del 3, Intron 2, Splice Region 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP11A1 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as rs121912811, CS021747, COSV51433766; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EGFR | c.1786C>T p.P596S | Missense Mutation (SNP) | VAF 13/285 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV51788518, COSV51816377; called by muse, mutect2
- TP53 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 14/52 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1060501191, COSV52666332, COSV52700326, COSV52746468; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 39/105 reads (37%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRL2 | c.1792C>T p.R598* | Nonsense Mutation (SNP) | VAF 30/81 reads (37%) | catalogued as rs940146446, COSV99586972; called by muse, mutect2, varscan2
- AREG | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 213/594 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as rs747434597, COSV52644992; called by muse, mutect2, varscan2
- ASCC3 | c.4931T>C p.I1644T | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1279132551, COSV64978134; called by muse, mutect2, varscan2
- CALN1 | c.248G>A p.R83H (on ENST00000329008 / NM_001017440.3; = p.R125H on NM_031468.4) | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.081); catalogued as rs771972574, COSV100210142, COSV61119556; called by muse, mutect2, varscan2
- CNTNAP3 | c.3731_3732del p.S1244Cfs*35 | Frame Shift Del (DEL) | VAF 28/234 reads (12%) | catalogued as rs1295672827; called by pindel, varscan2
- COL11A2 | c.857G>A p.G286E | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.972); catalogued as rs777716059, COSV59496299; called by muse, mutect2, varscan2
- COPG2 | c.532A>G p.I178V | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58406322; called by muse, mutect2, varscan2
- CSMD3 | c.4645A>T p.T1549S (on ENST00000297405 / NM_001363185.1; = p.T1445S on NM_052900.3) | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT tolerated (0.89); PolyPhen benign (0.023); catalogued as COSV52252426; called by muse, mutect2, varscan2
- DNHD1 | c.12345T>G p.Y4115* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as COSV54441249; called by muse, mutect2
- DSP | c.1487C>T p.T496M | Missense Mutation (SNP) | VAF 58/162 reads (36%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs374283517; called by muse, mutect2, varscan2
- DYNLRB1 | c.231A>T p.E77D | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55964437; called by muse, mutect2, varscan2
- GNRHR | c.741C>T p.H247= | Splice Region (SNP) | VAF 41/95 reads (43%) | catalogued as rs373475233; called by muse, mutect2, varscan2
- HEATR4 | c.1769G>A p.G590D | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772638121, COSV58575286; called by muse, mutect2, varscan2
- HELZ | c.4618C>T p.L1540F | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV62379767; called by muse, mutect2, varscan2
- HOXA6 | c.597C>G p.I199M | Missense Mutation (SNP) | VAF 87/413 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773221274, COSV56074198; called by muse, mutect2, varscan2
- HSPA12A | c.224C>T p.T75I | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV65023233; called by muse, mutect2, varscan2
- ITGA1 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201172852, COSV50889171; called by muse, mutect2, varscan2
- KCNC2 | c.1751C>T p.T584M | Missense Mutation (SNP) | VAF 173/445 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.629); catalogued as rs1378104354, COSV54374457; called by muse, mutect2, varscan2
- KSR2 | c.1606del p.L536Sfs*61 | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | catalogued as rs770565486; called by mutect2, pindel, varscan2
- MYH13 | c.5641T>C p.S1881P | Missense Mutation (SNP) | VAF 112/294 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as COSV52837022, COSV99353665; called by muse, mutect2, varscan2
- NLRP4 | c.1825G>A p.V609I | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.076); catalogued as COSV56716102, COSV56719004; called by muse, mutect2, varscan2
- NME8 | c.1474C>T p.Q492* | Nonsense Mutation (SNP) | VAF 46/136 reads (34%) | catalogued as COSV52253394; called by muse, mutect2, varscan2
- OR1N1 | c.457G>A p.V153I | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.069); catalogued as rs1256138583, COSV59196238; called by muse, mutect2, varscan2
- OR2M3 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 202/552 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs778299127, COSV71759161; called by muse, mutect2, varscan2
- OR5AR1 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 108/252 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs780660808, COSV57254597; called by muse, mutect2, varscan2
- OR5K1 | c.243G>A p.M81I | Missense Mutation (SNP) | VAF 169/461 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs188538173, COSV60304866; called by muse, mutect2, varscan2
- PIP4K2C | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 140/408 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV61606651; called by muse, varscan2
- PIWIL1 | c.1505G>A p.R502Q | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.621); catalogued as rs778735608, COSV55345392; called by muse, mutect2, varscan2
- PREX2 | c.3381C>A p.S1127R | Missense Mutation (SNP) | VAF 69/147 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.468); catalogued as COSV55787337; called by muse, mutect2, varscan2
- RFPL3 | c.449G>A p.G150E (on ENST00000249007 / NM_001098535.1; = p.G121E on NM_006604.2) | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); catalogued as rs1430239883, COSV50751389; called by muse, mutect2
- SH2D4A | c.23A>G p.E8G | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV56123832; called by muse, mutect2, varscan2
- SLC26A5 | c.637T>A p.F213I | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV59704151; called by muse, mutect2, varscan2
- SPEG | c.7081G>A p.G2361S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1361243543, COSV56675316; called by muse, mutect2, varscan2
- STXBP2 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 18/295 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs187320742, COSV55402074; ClinVar: uncertain significance; called by muse, mutect2
- TCHH | c.2933C>T p.P978L | Missense Mutation (SNP) | VAF 57/341 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100914868, COSV64276623; called by muse, mutect2, varscan2
- TERB2 | c.121G>C p.D41H | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61651202; called by muse, mutect2, varscan2
- WWC3 | c.2350G>T p.E784* | Nonsense Mutation (SNP) | VAF 12/19 reads (63%) | catalogued as COSV66505717; called by muse, mutect2
- ZNF676 | c.1439C>A p.P480H (on ENST00000650058; = p.P448H on NM_001001411.3) | Missense Mutation (SNP) | VAF 96/256 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV101236169, COSV68093203, COSV68094043; called by muse, mutect2, varscan2
- B2M | c.248_251del p.Y83Sfs*19 | Frame Shift Del (DEL) | VAF 83/239 reads (35%) | called by mutect2, pindel, varscan2
- MSL3 | c.590_593del p.X197_splice (on ENST00000312196 / NM_078629.4; = p.X31_splice on NM_006800.4) | Splice Site (DEL) | VAF 53/74 reads (72%) | called by mutect2, pindel, varscan2
- ATG4D | c.846G>A p.A282= | Silent (SNP) | VAF 39/93 reads (42%) | catalogued as rs531176373, COSV57265338; called by muse, mutect2, varscan2
- CACNG8 | c.123T>G p.T41= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV54415935; called by muse, mutect2, varscan2
- CCDC144A | c.48G>A p.P16= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV61403591; called by muse, mutect2
- CITED2 | c.135G>A p.Q45= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs1465982399, COSV62726724; called by muse, mutect2, varscan2
- COBL | c.2058A>G p.T686= | Silent (SNP) | VAF 68/261 reads (26%) | catalogued as rs759377799, COSV54352090; called by muse, mutect2, varscan2
- COPB2 | c.234C>T p.D78= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV60813272; called by muse, mutect2, varscan2
- CSPG5 | c.276G>A p.S92= | Silent (SNP) | VAF 34/100 reads (34%) | catalogued as COSV53132394; called by muse, mutect2, varscan2
- GBP4 | c.1089G>A p.T363= | Silent (SNP) | VAF 38/102 reads (37%) | catalogued as CM163985, COSV63255311, COSV63255316; called by muse, mutect2, varscan2
- GRIK5 | c.1026C>T p.H342= | Silent (SNP) | VAF 38/125 reads (30%) | catalogued as rs140981334, COSV53482332; called by muse, mutect2, varscan2
- PDE4DIP | c.228G>A p.V76= | Silent (SNP) | VAF 52/271 reads (19%) | called by muse, mutect2, varscan2
- PRAMEF20 | c.1386C>T p.N462= | Silent (SNP) | VAF 158/412 reads (38%) | catalogued as COSV57081021; called by muse, mutect2
- SAMD12 | c.333G>A p.L111= | Silent (SNP) | VAF 58/158 reads (37%) | catalogued as COSV100126179, COSV59053721; called by muse, mutect2, varscan2
- SCYL2 | c.1341C>T p.N447= | Silent (SNP) | VAF 54/140 reads (39%) | catalogued as COSV62569865; called by muse, mutect2, varscan2
- SLC15A2 | c.1293G>T p.V431= | Silent (SNP) | VAF 107/278 reads (38%) | catalogued as COSV55199492; called by muse, mutect2, varscan2
- SORL1 | c.3387G>A p.G1129= | Silent (SNP) | VAF 127/305 reads (42%) | catalogued as rs371319784; called by muse, mutect2, varscan2
- WDR4 | c.102C>T p.S34= | Silent (SNP) | VAF 31/92 reads (34%) | catalogued as COSV57734534; called by muse, mutect2, varscan2
- ZNF213 | c.228C>T p.P76= | Silent (SNP) | VAF 46/94 reads (49%) | catalogued as rs1309717329, COSV101206008, COSV67728104; called by muse, mutect2, varscan2
- HERC2P3 | n.2038G>A | RNA (SNP) | VAF 11/34 reads (32%) | catalogued as rs1429222482; called by mutect2, varscan2
- PABPC4 | c.972+254T>G | Intron (SNP) | VAF 20/80 reads (25%) | catalogued as COSV100790847; called by muse, mutect2, varscan2
- PRMT2 | c.654+2132C>T | Intron (SNP) | VAF 47/103 reads (46%) | catalogued as COSV99388446, COSV99388892; called by muse, mutect2, varscan2
